TCGA case TCGA-86-7955 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0d0d83d9-d558-4d38-977b-6f1b2471beda

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 62 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,772 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Days to treatment start: 27 days; Days to treatment end: 274 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 114 days; Days to treatment end: 190 days; Treatment dose: 62 Gy; Treatment outcome: Complete Response; Number of fractions: 31; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 823 days (2.3 years); Days to treatment end: 922 days (2.5 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,027 days (2.8 years); Days to treatment end: 1,057 days (2.9 years); Treatment dose: 36 Gy; Treatment outcome: Complete Response; Number of fractions: 18; Treatment anatomic sites: Regional Site.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 64.6 years (23,592 days); Days to diagnosis: 820 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (6 entries)
- Days to follow up: 14 days; Disease response: Tumor Free.
- Days to follow up: 508 days (1.4 years); Disease response: Tumor Free.
- Day 820 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 820 days (2.2 years).
- Days to follow up: 1,072 days (2.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-86-7955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.1; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-86-7955-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10.
- Sample TCGA-86-7955-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-86-7955-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Pulmonary function test indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Vepesid.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,072 days; disease-specific survival: no event (censored), 1,072 days; disease-free interval: event (new tumor event after initially disease-free), 820 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 820 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-86-7955-01A-11D-2183-01): tumor purity 0.73, ploidy 3.16, whole-genome doublings 1.
